Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A856, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A856-01A (Primary Tumor).

[page 1 of 2]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received

A. BASE OF RIGHT RENAL TUMOR F.S.

B. RIGHT RENAL TUMOR

826013
Carcinoma, papillary renal cell
Site: @ Kidney NOS C64.9
W 11/29/13

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

right renal mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

right renal mass

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

A. The specimen is received fresh and consists of a 0.3 x 0.2 x 0.1 cm, tan-red, irregular soft tissue fragment submitted fresh for intraoperative frozen section consultation. The specimen is submitted in toto for frozen and permanent sections in cassette FSA.

FROZEN SECTION DIAGNOSIS:

FSA. Kidney, right base of tumor, biopsy:
- NO TUMOR SEEN

B. The specimen consists of a 26.0 g, 4.8 x 3.8 x 3.5 cm, tan-brown, irregular soft tissue displaying a tan-brown, granular renal resection margin. The capsular margin is tan-pink to red and smooth with minimal attached overlying fat. The renal resection margin is inked blue, and the capsular margin is inked black. The specimen is serially sectioned to reveal a 2.4 x 2.3 x 1.8 cm, tan-yellow to white, friable, well-demarcated mass that grossly is less than 1 mm from both the capsular margin, as well as the renal resection margin. There are minimal amounts of adjacent uninvolved renal parenchyma.

The specimen is submitted in its entirety sequentially in cassettes B1-B12.

[page 2 of 2]
Please note, a representative portion is taken for tissue bank.

MICROSCOPIC EXAM

FINAL DIAGNOSIS:

A. BASE OF RIGHT RENAL TUMOR, EXCISIONAL BIOPSY:
- RENAL TUBULAR AND SOFT TISSUE, NO TUMOR SEEN.

B. RIGHT RENAL TUMOR, EN BLOC RESECTION:

PROCEDURE: PARTIAL NEPHRECTOMY.

LATERALITY: RIGHT.

TUMOR SITE: NOT PROVIDED.

TUMOR SIZE: 2.4 CM.

TUMOR FOCALITY: ONE FOCUS.

MACROSCOPIC EXTENT OF TUMOR: CANNOT ASSESS.

HISTOLOGIC TYPE: PAPILLARY CELL CARCINOMA, TYPE I.

TUMOR NECROSIS: FOCAL AT 2 %

HISTOLOGIC GRADE: GRADE 1-2.

MICROSCOPIC TUMOR EXTENSION: INTO PELVIS AND CAPSULE REGION.

SURGICAL MARGINS: MANY AREAS INVOLVED WITH TUMOR.

GEROTA'S FASCIAL MARGIN: CANNOT BE ASSESSED.

LYMPH-VASCULAR INVASION: NOT IDENTIFIED.

PATHOLOGICAL STAGE (pTNM)

APPEARS TO BE pT1a.

NONNEOPLASTIC KIDNEY:

- MILD ARTERIO- AND ARTERIOLOSCLEROSIS.

COMMENT: CONCURS WITH NEW MALIGNANCY. IMAGES ARE
AVAILABLE IN NOTIFIED VIA ON

Source: NCI Genomic Data Commons file 5785887e-a1d6-4bfa-bde1-09bb1c49517b (TCGA-MH-A856.41687B96-A8A7-46D1-B7A4-6181BB2BEE27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).